Gene-level copy-number profile of tumor specimen TCGA-02-2483-01A from TCGA case TCGA-02-2483, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 43.7 years (15,964 days).
Specimen TCGA-02-2483-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.e617c7e5-3903-4716-85c6-f51fdb81786b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-2483-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/40cdfb68-eafb-4aa5-8c29-1011fe1a761b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 107; copy number 1: 477; copy number 2: 4,382; copy number 3: 12,578; copy number 4: 39,130; copy number 5: 591; copy number 6: 1,139; copy number 7: 258; copy number 8: 146; copy number 9: 661; copy number 10: 284; copy number 11: 35; copy number 24: 1; copy number 26: 7; copy number 32: 1; copy number 38: 2; copy number 39: 6; copy number 40: 6; copy number 47: 1; copy number 67: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-02-2483-01A-01D-0784-01): tumor purity 0.73, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 107 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–1,550,103, 31 genes: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1.
- chr9:21,135,598–26,118,408, 76 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,006 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,651,731–9,828,271, 7 genes, copy number 26: PIK3CD, PIK3CD-AS1, AL691449.1, PIK3CD-AS2, CLSTN1, MZT1P1, AL357140.3.
- chr8:109,777,912–142,917,843, 403 genes, copy number 9–11 (broad region; genes not listed).
- chr9:117,197,118–138,203,325, 577 genes, copy number 9–10 (broad region; genes not listed).
- chr10:63,358,745–63,373,048, 2 genes, copy number 67: AC022022.2, MIR1296.
- chr10:68,827,531–68,895,432, 2 genes, copy number 40: STOX1, RNU6-697P.
- chr10:72,367,327–72,626,191, 4 genes, copy number 40 (within-gene range 2–40): MICU1, RNU6-805P, AC091769.1, SNX19P4.
- chr10:101,570,560–101,695,295, 6 genes, copy number 39 (within-gene range 2–39): DPCD, POLL, MIR3158-1, MIR3158-2, FBXW4, RNU6-1165P.
- chr10:106,550,106–106,551,121, 1 gene, copy number 24: RPL23AP59.
- chr10:121,478,332–121,598,458, 1 gene, copy number 32 (within-gene range 2–32): FGFR2.
- chr10:124,461,823–124,617,888, 2 genes, copy number 38 (within-gene range 2–38): LHPP, RPS10P18.
- chr10:129,768,844–129,769,435, 1 gene, copy number 47: AL157832.1.

Autosomal genes at a single copy (total copy number 1): 26. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
